Somatic mutation profile of tumor specimen BA3153D (aliquot aq-BA3153D) from BEATAML1.0 case 2664, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed phenotype acute leukemia, T/myeloid, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.0 years (18,252 days).
Specimen BA3153D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66c8711f-707e-46c9-8fe9-aaeb3c37620e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3391D (Solid Tissue Normal), aliquot aq-BA3391D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0a687a6-2d5b-419e-9504-9eec0d0ea961

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 65/108 reads (60%) | catalogued as COSV57198430; called by mutect2, varscan2
- ADNP | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 172/521 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZADH2 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 137/425 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
